Surgical pathology report (de-identified scan), TCGA case TCGA-MP-A4T7, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Mayo Clinic, specimen TCGA-MP-A4T7-01A (Primary Tumor).

Surgical Pathology

Requested By:

TISSUE DESCRIPTION:

A1 B1 C1 C2 D1 D2 E1 E2 F1 G1
Tissue from right middle lobe lung (25 grams, 8.0 x 4.0 x 2.4 cm),
from right lower lobe lung (5 grams, 3.5 x 2.6 x 2.6 cm), from right
lower lobe lung No.2 (4.0 x 0.7 x 0.6 cm), from right pleura
(No.1--1.0 x 1.0 x 0.6 cm and No.2--0.9 x 0.3 x 0.2 cm), from
diaphragm (2.0 x 1.3 x 0.6 cm) and mediastinal lymph node (station
9)

DIAGNOSIS:

Lung, right middle lobe, wedge excision: Grade 3 (of 4)
adenocarcinoma forming a 3.0 x 2.5 x 2.0 cm subpleural mass with
pleural invasion. Excision margins are free of tumor.

Lung, right lower lobe, wedge excision No.1: Grade 3 (of 4)
adenocarcinoma forming a 1.5 x 1.5 x 1.2 cm intraparenchymal mass.
Excision margins are free of tumor.

Lung, right lower lobe, wedge excision No.2: Negative for
carcinoma.

Pleura, right, biopsy No.1 and No.2: Invasive grade 3 (of 4)
adenocarcinoma, both specimens.

Diaphragm, biopsy: Invasive grade 3 (of 4) adenocarcinoma.

Lymph node, mediastinal, excision:
- No tumor identified in a single pulmonary ligament
(station 9) lymph node.

ICD-O-3

adenocarcinoma, NOS 8140/3

CQCF Site: lung, lower lobe C34.3

Path: lung, NOS C34.9

fw
10/27/12

Source: NCI Genomic Data Commons file 29d199e1-0c91-448e-b80b-b646c61492d0 (TCGA-MP-A4T7.D973F9E7-74DB-4880-B8F0-03E3887BDC36.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).